CCDI case PBCAKK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/b0ab1b07-d4b1-48aa-b2eb-f40b61479a45

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 20.3 years (7,398 days).

Biospecimens (3 samples)
- Sample 0DML9N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DML9P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DML9U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
